CCDI case PBBWZB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Oropharynx.
https://portal.gdc.cancer.gov/cases/3bebaa65-f179-44a1-918d-f9df13994ed5

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Oropharynx, NOS; Age at diagnosis: 14.8 years (5,419 days).

Biospecimens (3 samples)
- Sample 0DJO4O: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJO53: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJO5J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
